Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PD, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PD-01A (Primary Tumor).

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Body of stomach Ck. 2
3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "12a lymph node":

- Metastasis of carcinoma in one lymph node (1/1).

2 - "8a lymph node":

5 of 6 lymph nodes involved by metastatic carcinoma (5/6).

3 - "Stomach + omentum":

- Moderately differentiated adenocarcinoma, extending from the esophagogastric junction to the duodenum, measuring 8.7 x 6.5cm (measured macroscopically) infiltrating the segment wall until the adipose perigastric tissue;

- Perineural invasion present;

- Angiolymphatic invasion present;

- Moderate peritumoral desmoplasia;

- Sparse peritumoral lymphocitary infiltrate;

- Surgical margins uninvolved by neoplasia;

- Congested non-neoplastic segment;

- Omentum segment uninvolved by neoplasia;

- Carcinoma metastasis on the 13 lymph nodes dissected in small curvature (13/13) and six nodes of six dissected of greater curvature (6/6).

4 - "Spleen":

- Spleen congested.

5 - "11p lymph node":

- 1 metastatic of 2 lymph nodes dissected (1/2).

6 - "Esophageal margin":

- Margin uninvolved by neoplasia.

Pathological Staging pT3 pN3b

Diagnostic Discrepancy		☒
HPV-A Discrepancy		☒

Source: NCI Genomic Data Commons file 429cbc0f-0089-4f1f-8d4a-b41b631ba3c0 (TCGA-VQ-A8PD.DE2703ED-489C-4185-A971-493A005DA974.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).